Somatic mutation profile of tumor specimen TCGA-G9-A9S4-01A (aliquot TCGA-G9-A9S4-01A-11D-A41K-08) from TCGA case TCGA-G9-A9S4, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.1 years (22,684 days).
Specimen TCGA-G9-A9S4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b70542ce-2b8d-48e7-9316-ce802d82307a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-A9S4-10A (Blood Derived Normal), aliquot TCGA-G9-A9S4-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24a574f2-70ad-4d75-a2ff-49e6a7a486db

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 24, Silent 7, Frame Shift Del 3, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 29/53 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AMDHD1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1462145993, COSV99900177; called by muse, mutect2, varscan2
- ARHGEF5 | c.2657C>T p.T886I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs1484180962, COSV99282523; called by mutect2, varscan2
- CD3D | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.666); catalogued as COSV100329334; called by muse, mutect2, varscan2
- CYLC1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs375048079, COSV100253999; called by muse, varscan2
- GTPBP1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV53283863; called by muse, mutect2, varscan2
- HADH | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs746680125, COSV58848416; called by muse, mutect2, varscan2
- HDAC9 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV67767903; called by muse, mutect2, varscan2
- HRH4 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56930130; called by muse, mutect2, varscan2
- KCNV1 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765741797, COSV52084728; called by muse, mutect2, varscan2
- KRT6B | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV52885708, COSV99360395; called by muse, mutect2, varscan2
- MRPS22 | c.785G>A p.R262H (on ENST00000310776 / NM_001363893.1; = p.R263H on NM_020191.4) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as rs1001683797, COSV60350659; called by muse, mutect2
- MSI2 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as rs757898294, COSV99401563; called by muse, mutect2, varscan2
- OR4A16 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs1467971769, COSV100125000; called by muse, mutect2
- OR5D14 | c.29T>C p.M10T | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100162081, COSV100162577; called by muse, mutect2, varscan2
- P2RX4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV100078671; called by muse, mutect2
- RPL10L | c.357T>G p.F119L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV100022375; called by muse, mutect2, varscan2
- SASS6 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764962644, COSV99790548; called by muse, mutect2, varscan2
- SLC24A1 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV56054105; called by muse, mutect2, varscan2
- SNX33 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1253814510, COSV100145721; called by muse, mutect2, varscan2
- SORCS1 | c.2190C>T p.C730= | Splice Region (SNP) | VAF 7/32 reads (22%) | catalogued as rs539985772, COSV99542907, COSV99548202; called by muse, mutect2, varscan2
- SSTR1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs995593676, COSV99942683; called by muse, mutect2, varscan2
- TRANK1 | c.8297G>T p.C2766F | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV100081313, COSV57148442; called by muse, mutect2
- TUBB4A | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.964); catalogued as COSV51161099; called by muse, mutect2, varscan2
- ZNF700 | c.1438G>C p.G480R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99583236; called by muse, mutect2, varscan2
- CLDND2 | c.280del p.Q94Rfs*15 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- INTS8 | c.592del p.S198Lfs*5 | Frame Shift Del (DEL) | VAF 41/83 reads (49%) | called by mutect2, pindel, varscan2
- OSBPL10 | c.1075del p.T359Pfs*41 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | called by pindel, varscan2
- ZNF682 | c.1018_1026del p.P340_K342del | In Frame Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- CERCAM | c.1422G>A p.T474= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs748241580, COSV65712260; called by muse, mutect2, varscan2
- FUT3 | c.843C>T p.Y281= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs765480346, COSV99744216; called by muse, mutect2, varscan2
- MYL12A | c.426C>T p.Y142= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99470094; called by muse, mutect2, varscan2
- PCNX1 | c.3009C>T p.I1003= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV99453845; called by muse, mutect2, varscan2
- RMDN1 | c.930C>T p.F310= | Silent (SNP) | VAF 78/116 reads (67%) | catalogued as COSV68830615; called by muse, mutect2, varscan2
- RYR2 | c.2523G>A p.K841= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV100767560; called by muse, mutect2
- RYR2 | c.4752G>A p.P1584= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs780111656, COSV63658984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
